Somatic mutation profile of tumor specimen TCGA-2G-AAKG-05A (aliquot TCGA-2G-AAKG-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAKG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 22.9 years (8,353 days).
Specimen TCGA-2G-AAKG-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38b0a377-abf3-4d0f-b6b4-167bedeef683.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKG-10A (Blood Derived Normal), aliquot TCGA-2G-AAKG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e7e6975-07ac-4d6c-8c5e-81be6ab9b4fe

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Intron 3, Splice Site 2, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.4918C>A p.L1640M | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771733955; called by muse, mutect2, varscan2
- BEND6 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | catalogued as rs928555916, COSV66070555; called by muse, mutect2, varscan2
- BRINP3 | c.1274C>G p.S425W | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV66514310, COSV66540055; called by muse, mutect2
- KANSL3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867052325; called by muse, mutect2, varscan2
- NYAP1 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs749316345; called by muse, mutect2, varscan2
- SCRIB | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57589675; called by muse, mutect2, varscan2
- SMARCA2 | c.3473A>C p.D1158A | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM122550; called by muse, mutect2, varscan2
- TAS2R8 | c.294G>C p.W98C | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99553532; called by muse, mutect2, varscan2
- TNS1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1293649446, COSV50749710; called by muse, mutect2, varscan2
- ABCC9 | c.1397T>C p.L466P | Missense Mutation (SNP) | VAF 54/478 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ABT1 | c.438+1G>T p.X146_splice | Splice Site (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- ALPG | c.92G>C p.W31S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF5 | c.315dup p.P106Tfs*79 | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- L2HGDH | c.1321_1323del p.P441del | In Frame Del (DEL) | VAF 48/320 reads (15%) | called by mutect2, pindel, varscan2
- MROH2A | c.3109G>A p.G1037S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PRICKLE2 | c.768+1G>T p.X256_splice (on ENST00000295902; = p.X200_splice on NM_198859.4) | Splice Site (SNP) | VAF 51/243 reads (21%) | called by muse, mutect2, varscan2
- REV3L | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A23 | c.1874dup p.N625Kfs*4 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- SLC2A7 | c.804C>A p.H268Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2
- SMARCA5 | c.470_473del p.E157Afs*18 | Frame Shift Del (DEL) | VAF 69/351 reads (20%) | called by mutect2, pindel, varscan2
- USP46 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XDH | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFR2 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2
- DISP3 | c.2238C>T p.F746= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs769487978, COSV53823911; called by muse, mutect2, varscan2
- FAT4 | c.333T>C p.L111= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1192577715; called by muse, mutect2, varscan2
- GPATCH8 | c.240C>A p.G80= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- MRPS5 | c.1215A>G p.K405= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- MTA2 | c.459C>T p.Y153= | Silent (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- NMRAL1 | c.189C>T p.V63= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- SERPINA10 | c.421C>T p.L141= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- SLC12A3 | c.1224A>T p.T408= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- ZC3H7B | c.1488C>T p.Y496= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs951145180, COSV60964856; called by muse, mutect2, varscan2
- ATIC | c.291-38A>T | Intron (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- CAPN1 | c.*6G>T | 3'UTR (SNP) | VAF 11/35 reads (31%) | catalogued as rs755115411; called by muse, mutect2, varscan2
- CAPN1 | c.*7G>T | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99658540; called by muse, mutect2, varscan2
- CLN3 | c.223-46T>C | Intron (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- DNAH7 | c.1353+1600A>T | Intron (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
